TCGA case TCGA-3B-A9HS — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/00eaaf62-c43e-4555-9134-1e5593386fdb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 1,366 days (3.7 years).

Diagnoses (7)
1. Myxoid leiomyosarcoma (the primary disease): ICD-O-3 morphology code: 8896/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 60.1 years (21,946 days); Year of diagnosis: 2008; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Other / Pelvis; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 25; Tumor length measurement: 19; Tumor width measurement: 17.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 30; Necrosis present: Yes.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 30.
2. Recurrence of diagnosis 1 (Myxoid leiomyosarcoma). Age at diagnosis: 60.5 years (22,085 days); Days to diagnosis: 139 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 3.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 1.5; Tumor length measurement: 3; Tumor width measurement: 2.5.
3. Metastasis of diagnosis 1 (Myxoid leiomyosarcoma), site: Pelvis, NOS. Age at diagnosis: 60.6 years (22,126 days); Days to diagnosis: 180 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.7; Tumor length measurement: 6; Tumor width measurement: 4.
4. Recurrence of diagnosis 1 (Myxoid leiomyosarcoma). Age at diagnosis: 60.9 years (22,244 days); Days to diagnosis: 298 days; Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 3.4; Tumor width measurement: 3.
5. Metastasis of diagnosis 1 (Myxoid leiomyosarcoma), site: Lymph nodes of inguinal region or leg. Age at diagnosis: 61.5 years (22,475 days); Days to diagnosis: 529 days (1.4 years); Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 2.1; Tumor width measurement: 1.8.
6. Metastasis of diagnosis 1 (Myxoid leiomyosarcoma), site: Abdomen, NOS. Age at diagnosis: 61.8 years (22,572 days); Days to diagnosis: 626 days (1.7 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.5; Tumor length measurement: 8; Tumor width measurement: 6.6.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 5.1; Tumor width measurement: 4.7.
7. Metastasis of diagnosis 1 (Myxoid leiomyosarcoma), site: Pelvis, NOS. Age at diagnosis: 62.7 years (22,888 days); Days to diagnosis: 942 days (2.6 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 19; Tumor length measurement: 5.2; Tumor width measurement: 6.6.

Follow-up (8 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 3.
- Day 139 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 139 days; Discontiguous lesion count: 3.
- Day 180 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 180 days; Discontiguous lesion count: 3.
- Day 298 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 298 days.
- Day 529 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of inguinal region or leg; Days to progression: 529 days (1.4 years).
- Day 626 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 626 days (1.7 years).
- Day 942 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 942 days (2.6 years).
- Days to follow up: 1,366 days (3.7 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9HS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-3B-A9HS-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9HS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9HS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: Yes; Discontinuous lesions count: 3; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Pelvis & Arm.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 568; Days from index date to pharmaceutical treatment ended: 592; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 568; Days from index date to pharmaceutical treatment ended: 592; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1034; Days from index date to pharmaceutical treatment ended: 1132; Pharmaceutical therapy drug name: gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1034; Days from index date to pharmaceutical treatment ended: 1132; Pharmaceutical therapy drug name: docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1202; Days from index date to pharmaceutical treatment ended: 1243; Pharmaceutical therapy drug name: temozolomide; Pharmaceutical treatment ongoing indicator: No.
- Radiation treatment 1: Days from index date to radiation therapy started: 216; Days from index date to radiation therapy ended: 257; Radiation therapy type: External; Radiation total dose: 5040; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 28; Radiation therapy site: Regional site; Radiation therapy ongoing indicator: No.
- Radiation treatment 2: Days from index date to radiation therapy started: 187; Days from index date to radiation therapy ended: 187; Radiation therapy type: Internal; Radiation total dose: 52.45; Radiation adjuvant units: mCi; Radiation adjuvant fractions total: 1; Radiation therapy site: Regional site; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,366 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,366 days; disease-free interval: event (new tumor event after initially disease-free), 139 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 139 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9HS-01A-11D-A38Y-01): tumor purity 0.57, ploidy 3.29, whole-genome doublings 1.
